Somatic mutation profile of tumor specimen C3L-01913-01 (aliquot CPT0092690009) from CPTAC case C3L-01913, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 55.0 years (20,093 days).
Specimen C3L-01913-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af0c2789-de3a-4885-bf5d-d47a1e492865.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01913-31 (Blood Derived Normal), aliquot CPT0093810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61845078-b637-4257-a4a0-4aa782bba1f2

The open-access MAF lists 22,327 somatic variants for this specimen: 15,262 protein-altering or splice-affecting, 4,424 silent, 2,641 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13,347, Silent 4,424, Intron 1,347, Nonsense Mutation 1,281, 3'UTR 453, RNA 371, Splice Site 282, Splice Region 218, 5'UTR 218, 5'Flank 140, 3'Flank 111, Frame Shift Ins 88.

Variants (750 of 22,327; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3661C>T p.R1221C | Missense Mutation (SNP) | VAF 58/620 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63751215, CM030401; ClinVar: pathogenic; called by muse, mutect2
- ABCC6 | c.855C>T p.T285= | Silent (SNP) | VAF 64/686 reads (9%) | catalogued as rs4780605; ClinVar: pathogenic / likely benign; called by muse, mutect2
- ACTA2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 49/418 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.042); catalogued as rs794728021, CM092900, COSV56515596; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACVRL1 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs1085307405, CM023314, COSV66360378; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGK | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 41/217 reads (19%) | catalogued as rs746709222, COSV62595320; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.1530dup p.G511Wfs*26 | Frame Shift Ins (INS) | VAF 74/624 reads (12%) | catalogued as rs1554081749; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 141/509 reads (28%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 107/365 reads (29%) | catalogued as rs1555069657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.2554C>T p.Q852* | Nonsense Mutation (SNP) | VAF 101/389 reads (26%) | catalogued as rs758081262, CM157871, COSV53742178; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.6415G>T p.E2139* | Nonsense Mutation (SNP) | VAF 118/360 reads (33%) | catalogued as rs1339238483, CD961806, COSV53731701; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCKDHB | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 64/714 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751953459, CM032854, COSV100243769, COSV100243915; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CBLIF | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 245/851 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs121434322, CM051061; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 97/718 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs373364873, COSV55736613; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKL5 | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 60/576 reads (10%) | catalogued as rs267608395, CM090451, COSV101183994; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHRNG | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 55/477 reads (12%) | catalogued as rs764266722, CM1110242, COSV51329061; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLN5 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 100/342 reads (29%) | catalogued as rs386833971, CM120887, COSV66285061; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 16/106 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- CUL3 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 47/455 reads (10%) | catalogued as rs201496024; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DCAF17 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 20/265 reads (8%) | catalogued as rs1470826074, COSV104412948; ClinVar: likely pathogenic; called by muse, mutect2
- DHCR7 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 77/713 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs535561852, CM000698, COSV62794545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAI2 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 78/656 reads (12%) | catalogued as rs200708870; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 38/455 reads (8%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as rs755995375, COSV61576496; called by muse, mutect2
- DYRK1A | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 22/125 reads (18%) | catalogued as rs1057518204, CM162102, COSV100117767, COSV58296087; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EEF1A2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 104/332 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.18); catalogued as rs886042041; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ERBB3 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 143/468 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV57250290, COSV57259763, COSV57263441; called by muse, mutect2, varscan2
- EYA1 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 99/883 reads (11%) | catalogued as rs1131691667, CM001984, COSV58158250; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.4337-1G>T p.X1446_splice | Splice Site (SNP) | VAF 84/676 reads (12%) | catalogued as rs1555397424, CS075135, CS118010, COSV57309956; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 69/593 reads (12%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- FBXW7 | c.832C>T p.R278* (on ENST00000281708 / NM_001349798.2; = p.R198* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 48/269 reads (18%) | hotspot (GDC flag); catalogued as COSV55891638; called by muse, varscan2
- FH | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 64/476 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs863224007, CM030855; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FUS | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 76/562 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs387906628, CM1010304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GATA1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 83/528 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104894809, CM020277, COSV64962346, COSV64964277; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAL | c.733C>T p.R245* (on ENST00000269162 / NM_001142339.3; = p.R322* on NM_182978.4) | Nonsense Mutation (SNP) | VAF 52/244 reads (21%) | catalogued as rs1252185897, CM135135, COSV52323513; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN2A | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 101/606 reads (17%) | catalogued as rs397518472, CM138216, COSV58045574, COSV58045723; ClinVar: pathogenic; called by muse, varscan2
- HDAC3 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 112/437 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1554216303, CM162330, COSV59496145; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HDAC8 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 38/287 reads (13%) | catalogued as rs886041936; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IFT140 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 48/207 reads (23%) | catalogued as rs762817061; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IL7R | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 52/524 reads (10%) | hotspot (GDC flag); catalogued as rs201559094, CM045175, COSV57405649; called by muse, mutect2
- LMNA | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 44/316 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs267607594, CM085515; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- LMNA | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 89/749 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267607571, CM050658, CM1414666, COSV61542038; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LMX1B | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 70/537 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs886039576, CM042391, COSV62742576; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MED13L | c.6488C>T p.S2163L | Missense Mutation (SNP) | VAF 187/693 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565981137; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 63/481 reads (13%) | catalogued as rs63749947, CD076834, CM076317, COSV51875855, COSV51883753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTC | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 131/418 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs66550389, CM062966, CM062967, CM910275, COSV50000649, COSV50002957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PANK2 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 91/565 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs137852962, CM014236; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 138/504 reads (27%) | catalogued as rs137853001, CM012633, COSV57282024; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 72/274 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 43/134 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1553821144, COSV55877939, COSV55937337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 29/131 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1064793732, CM126690, COSV55881636, COSV55977337; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.53-1G>A p.X18_splice | Splice Site (SNP) | VAF 70/586 reads (12%) | catalogued as rs775511838; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 140/476 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- POU1F1 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 71/499 reads (14%) | catalogued as rs104893760, CM950968, COSV55461353; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 126/458 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPRD | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 52/457 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs764400127, COSV61926988, COSV61964410; called by muse, mutect2, varscan2
- PYGM | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 78/465 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757681143, CM066980, COSV99377384; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAD51C | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 79/556 reads (14%) | catalogued as rs1567785872, COSV99542479; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAF1 | c.778A>C p.T260P | Missense Mutation (SNP) | VAF 57/475 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1085307553; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RASA1 | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 116/482 reads (24%) | catalogued as rs886041740; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 47/526 reads (9%) | catalogued as rs1131690904, CD145444, CM133194; ClinVar: pathogenic; called by muse, mutect2
- RB1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 147/540 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs772678500, COSV57305106; ClinVar: uncertain significance; called by muse, varscan2
- RB1 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 30/218 reads (14%) | hotspot (GDC flag); catalogued as rs398123331, CM951106, COSV57296693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RPE65 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 175/586 reads (30%) | catalogued as rs61752877, CM983760; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- RSPH1 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 42/270 reads (16%) | catalogued as rs753105954; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 23/158 reads (15%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, mutect2, varscan2
- SCN9A | c.1979C>T p.T660M (on ENST00000303354; = p.T649M on NM_002977.3) | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs200965749, COSV57620767; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- SETBP1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 62/446 reads (14%) | catalogued as rs1568234874, COSV56319931; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SGCA | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 44/573 reads (8%) | catalogued as rs1057516664; ClinVar: likely pathogenic; called by muse, mutect2
- SLC19A2 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 66/559 reads (12%) | catalogued as rs74315373, CM991264, COSV52546848; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPAST | c.1169T>C p.M390T | Missense Mutation (SNP) | VAF 56/530 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs1131691977; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 125/653 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.99592C>T p.R33198* (on ENST00000591111; = p.R25774* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 37/368 reads (10%) | catalogued as rs1553488049, COSV60194588; ClinVar: likely pathogenic; called by muse, mutect2
- VARS2 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 54/428 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs139515727; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.7603C>T p.R2535* | Nonsense Mutation (SNP) | VAF 69/548 reads (13%) | catalogued as rs386834107, CM041277, COSV62134139; ClinVar: likely pathogenic; called by muse, varscan2
- A1BG | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200130951, COSV54051137; called by muse, mutect2, varscan2
- A1BG | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as rs1206591663, COSV54052428; called by muse, mutect2
- A1BG | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1267963702; called by muse, mutect2
- A1CF | c.989C>A p.S330Y | Missense Mutation (SNP) | VAF 156/618 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV50962758; called by muse, mutect2, varscan2
- A2M | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs780559648, COSV104404246; called by muse, mutect2, varscan2
- AACS | c.1894G>A p.G632S | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs780717330; called by muse, varscan2
- AADAT | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV61786973; called by muse, mutect2, varscan2
- AAK1 | c.1906C>T p.L636F | Missense Mutation (SNP) | VAF 154/620 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV68646057; called by muse, varscan2
- AAK1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 59/212 reads (28%) | catalogued as rs1454552225, COSV68646763; called by muse, mutect2, varscan2
- AARS1 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 101/730 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs772849771, COSV55747281; called by muse, mutect2, varscan2
- AARS1 | c.2222C>T p.T741M | Missense Mutation (SNP) | VAF 85/677 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as rs148383122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AATK | c.2701G>A p.D901N (on ENST00000326724 / NM_001080395.3; = p.D798N on NM_004920.2) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs760841585; called by muse, mutect2, varscan2
- ABCA1 | c.5572G>A p.V1858M | Missense Mutation (SNP) | VAF 55/490 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as rs150801208, COSV99058235; called by muse, mutect2, varscan2
- ABCA1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 172/634 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs138438101, COSV66057789; called by muse, varscan2
- ABCA10 | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 14/244 reads (6%) | catalogued as COSV104393371; called by muse, mutect2
- ABCA12 | c.1312G>A p.E438K (on ENST00000272895 / NM_173076.3; = p.E120K on NM_015657.3) | Missense Mutation (SNP) | VAF 167/560 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs562998767, COSV55967677; called by muse, mutect2, varscan2
- ABCA12 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as COSV55954315; called by muse, mutect2, varscan2
- ABCA12 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 156/603 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.061); catalogued as rs773100250, COSV55953508; called by muse, varscan2
- ABCA2 | c.7133C>T p.S2378L (on ENST00000614293; = p.S2348L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/434 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs969345170; called by muse, mutect2, varscan2
- ABCA3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 110/738 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs746902527, COSV57052156; called by muse, mutect2, varscan2
- ABCA4 | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 74/706 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV64673239; called by muse, varscan2
- ABCA5 | c.2779G>T p.D927Y | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV67017820; called by muse, varscan2
- ABCA7 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs139251928; called by mutect2, varscan2
- ABCA8 | c.3593C>A p.S1198Y | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV52197160; called by muse, mutect2, varscan2
- ABCA9 | c.3778G>T p.D1260Y | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1266184514; called by muse, mutect2, varscan2
- ABCB1 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 54/403 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.87); catalogued as rs2235036; called by muse, mutect2, varscan2
- ABCB1 | c.1102A>T p.I368L | Missense Mutation (SNP) | VAF 70/560 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV99711753; called by muse, varscan2
- ABCB10 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 53/359 reads (15%) | catalogued as rs1370648698; called by muse, mutect2, varscan2
- ABCB10 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1033424395; called by muse, varscan2
- ABCB4 | c.2701G>T p.E901* | Nonsense Mutation (SNP) | VAF 121/456 reads (27%) | catalogued as COSV55934686, COSV55936859; called by muse, mutect2, varscan2
- ABCB5 | c.1283G>T p.S428I | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs753417803, COSV99329509; called by muse, mutect2, varscan2
- ABCB6 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765195871, COSV54695466; called by muse, varscan2
- ABCB7 | c.1922C>T p.S641L (on ENST00000373394 / NM_001271696.3; = p.S642L on NM_004299.6) | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1002483499, COSV99504453; called by muse, mutect2
- ABCB8 | c.1033C>T p.R345C (on ENST00000297504 / NM_001282291.2; = p.R328C on NM_007188.5) | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754606258, COSV52502008; called by muse, mutect2, varscan2
- ABCB8 | c.1439+8C>T | Splice Region (SNP) | VAF 21/113 reads (19%) | catalogued as rs199726798; called by muse, mutect2, varscan2
- ABCC1 | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 39/401 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368340485; called by muse, mutect2, varscan2
- ABCC1 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773203154; called by muse, mutect2, varscan2
- ABCC11 | c.3904G>A p.D1302N | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174748693, COSV62321883; called by muse, mutect2
- ABCC2 | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 186/770 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV64970869; called by muse, mutect2, varscan2
- ABCC3 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 48/393 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs143084758; called by muse, mutect2, varscan2
- ABCC3 | c.4441G>A p.A1481T | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs539211035, COSV53318763; called by muse, mutect2, varscan2
- ABCC6 | c.4130C>T p.T1377M | Missense Mutation (SNP) | VAF 72/480 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs371122482; called by muse, varscan2
- ABCC8 | c.4523C>T p.T1508M | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376693586; called by muse, mutect2, varscan2
- ABCC9 | c.3094C>A p.Q1032K | Missense Mutation (SNP) | VAF 56/484 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV99685036; called by muse, varscan2
- ABCD2 | c.1738C>A p.L580M | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58053290; called by muse, mutect2
- ABCE1 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs550948053, COSV56846273; called by muse, mutect2, varscan2
- ABCF3 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 60/481 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs771778897, COSV99490796; called by muse, mutect2, varscan2
- ABCG1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 70/513 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs959974308, COSV59209161; called by muse, mutect2, varscan2
- ABCG4 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs990707876; called by muse, mutect2, varscan2
- ABCG8 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 85/842 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV55390267; called by muse, mutect2, varscan2
- ABCG8 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 59/448 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs199553576; called by muse, mutect2, varscan2
- ABCG8 | c.1832G>T p.R611I | Missense Mutation (SNP) | VAF 119/758 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV55393098, COSV55396475; called by muse, mutect2, varscan2
- ABI3BP | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.023); catalogued as rs202185024, COSV52541411; called by muse, mutect2, varscan2
- ABL2 | c.2693G>A p.R898Q (on ENST00000502732 / NM_007314.4; = p.R883Q on NM_005158.5) | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as rs558127546; called by muse, mutect2, varscan2
- ABO | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 84/586 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1211406855; called by muse, mutect2, varscan2
- ABRAXAS1 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 63/566 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1345611154, COSV55029706, COSV99788370; called by muse, mutect2, varscan2
- ABRAXAS2 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.877); catalogued as COSV53717177; called by muse, mutect2, varscan2
- AC004922.1 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs763336010, COSV53163817; called by muse, mutect2, varscan2
- AC008397.2 | c.1416G>T p.E472D | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV53208313; called by muse, mutect2, varscan2
- AC011005.1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 95/770 reads (12%) | catalogued as rs745777281; called by muse, varscan2
- AC013489.1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 34/351 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs761657528; called by muse, mutect2
- AC090517.4 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs1016910768; called by muse, mutect2
- AC092718.8 | c.217A>T p.N73Y | Missense Mutation (SNP) | VAF 88/610 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100202837; called by muse, varscan2
- AC098582.1 | c.704A>G p.H235R | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs766979153; called by muse, mutect2, varscan2
- AC099489.1 | c.4114G>A p.A1372T | Missense Mutation (SNP) | VAF 100/391 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.277); catalogued as rs367723748; called by muse, varscan2
- AC100868.1 | c.2070G>T p.*690Yext*7 | Nonstop Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV51841541; called by muse, mutect2
- AC126283.2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 54/502 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101144202; called by muse, varscan2
- ACACA | c.3050G>A p.R1017Q | Missense Mutation (SNP) | VAF 114/446 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1385648978; called by muse, mutect2, varscan2
- ACAN | c.4370T>C p.L1457P | Missense Mutation (SNP) | VAF 112/800 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.054); catalogued as COSV61359738; called by muse, varscan2
- ACAP1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 52/93 reads (56%) | catalogued as rs757840962, COSV99341454; called by muse, mutect2, varscan2
- ACAP2 | c.2062G>A p.G688R | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100463041; called by muse, varscan2
- ACAP3 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 43/436 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs1172362872; called by muse, mutect2, varscan2
- ACAP3 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs369571322; called by muse, mutect2
- ACAT2 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV100364906, COSV58457385; called by muse, mutect2
- ACBD3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 131/544 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1278923333, COSV64729525; called by muse, mutect2, varscan2
- ACCS | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs776507293; called by muse, mutect2, varscan2
- ACCSL | c.1618A>C p.K540Q | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.017); catalogued as rs750154415; called by muse, mutect2
- ACD | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.284); catalogued as COSV54665649, COSV54666110; called by muse, mutect2, varscan2
- ACE | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 97/763 reads (13%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.635); catalogued as rs748868465; called by muse, mutect2, varscan2
- ACE | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 72/593 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV99326598; called by muse, mutect2, varscan2
- ACE2 | c.2049C>A p.F683L | Missense Mutation (SNP) | VAF 111/304 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); catalogued as rs773848804, COSV53024902; called by muse, mutect2, varscan2
- ACE2 | c.1990C>A p.L664I | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.06); catalogued as COSV53023908; called by muse, mutect2, varscan2
- ACIN1 | c.3511C>T p.R1171* | Nonsense Mutation (SNP) | VAF 34/261 reads (13%) | catalogued as COSV99399405; called by muse, mutect2, varscan2
- ACIN1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 31/386 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV52980981; called by muse, mutect2
- ACIN1 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 53/417 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.174); catalogued as rs745432174, COSV52976144; called by muse, mutect2, varscan2
- ACKR1 | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV63672905; called by muse, mutect2, varscan2
- ACKR1 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.888); catalogued as rs1469550773; called by muse, mutect2, varscan2
- ACLY | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs541819037; called by muse, mutect2, varscan2
- ACLY | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 34/387 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782250367; called by muse, mutect2
- ACO2 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 57/385 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs758983751; called by muse, mutect2, varscan2
- ACO2 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 133/472 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs753640444; called by muse, mutect2, varscan2
- ACOT12 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs371159125; called by muse, mutect2, varscan2
- ACOXL | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV61328323; called by muse, mutect2, varscan2
- ACP2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 201/753 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs540880065; called by muse, mutect2, varscan2
- ACR | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1283266951; called by muse, mutect2, varscan2
- ACRBP | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 36/320 reads (11%) | catalogued as rs773914526; called by muse, mutect2, varscan2
- ACRBP | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 105/345 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs781225787; called by muse, mutect2, varscan2
- ACSBG2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 49/394 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs773930895, COSV53124383; called by muse, mutect2, varscan2
- ACSL1 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 31/325 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs1346627652, COSV55661967; called by muse, mutect2, varscan2
- ACSL3 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs765377905; called by muse, mutect2, varscan2
- ACSM2A | c.947G>A p.R316Q (on ENST00000219054; = p.R237Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as rs199633879; called by muse, mutect2
- ACSM2A | c.1075G>T p.E359* (on ENST00000219054; = p.E280* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 38/287 reads (13%) | catalogued as COSV54585960; called by muse, mutect2, varscan2
- ACSM2B | c.1327C>A p.L443I | Missense Mutation (SNP) | VAF 32/477 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as rs953257506; called by muse, mutect2
- ACSM4 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV68066519; called by muse, mutect2, varscan2
- ACSS1 | c.1610G>T p.R537L | Missense Mutation (SNP) | VAF 29/387 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV60219094; called by muse, mutect2
- ACSS3 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 12/176 reads (7%) | catalogued as COSV54101173; called by muse, mutect2
- ACSS3 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760262489; called by muse, mutect2, varscan2
- ACSS3 | c.1863A>C p.K621N | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54093383; called by muse, mutect2, varscan2
- ACTL6A | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs757498550; called by muse, mutect2, varscan2
- ACTR2 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs757353258, COSV53199530; called by muse, mutect2, varscan2
- ACTR3 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV54302055; called by muse, varscan2
- ACTR5 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as rs190086095; called by muse, mutect2, varscan2
- ACTRT1 | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64418954, COSV64420046; called by muse, mutect2, varscan2
- ADAL | c.18G>T p.E6D | Missense Mutation (SNP) | VAF 102/344 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1356783642; called by muse, mutect2, varscan2
- ADAM10 | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 71/596 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99545861; called by muse, mutect2, varscan2
- ADAM11 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99567537; called by muse, mutect2, varscan2
- ADAM11 | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1037353307, COSV52344942; called by muse, mutect2, varscan2
- ADAM15 | c.747C>A p.F249L | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55125821, COSV55126633; called by muse, mutect2, varscan2
- ADAM18 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as rs771734296, COSV55845824; called by muse, mutect2, varscan2
- ADAM19 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 42/290 reads (14%) | catalogued as rs775287603, COSV57433089; called by muse, mutect2, varscan2
- ADAM20 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 39/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs773132300, COSV99833569; called by muse, mutect2
- ADAM28 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV56099232; called by muse, mutect2, varscan2
- ADAM30 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 50/377 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV65561284; called by muse, mutect2, varscan2
- ADAM32 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 24/207 reads (12%) | catalogued as COSV65953409; called by muse, mutect2, varscan2
- ADAM8 | c.1802G>A p.R601H | Missense Mutation (SNP) | VAF 74/298 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs777265811; called by muse, varscan2
- ADAM9 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 85/356 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); catalogued as rs1344174952, COSV65946589; called by muse, mutect2, varscan2
- ADAMTS10 | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV54355665; called by muse, mutect2
- ADAMTS12 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 35/517 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as COSV61254856; called by muse, mutect2
- ADAMTS13 | c.4013C>A p.A1338D | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV52469441; called by muse, mutect2
- ADAMTS15 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 11/199 reads (6%) | catalogued as rs1176143861; called by muse, mutect2
- ADAMTS16 | c.3328G>A p.A1110T | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs765764695, COSV56998986; called by muse, mutect2
- ADAMTS17 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 64/489 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as rs763161481; called by muse, mutect2, varscan2
- ADAMTS19 | c.2375G>A p.G792E | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487326673; called by muse, mutect2, varscan2
- ADAMTS20 | c.3729G>T p.E1243D | Missense Mutation (SNP) | VAF 34/361 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.331); catalogued as COSV67134711; called by muse, mutect2
- ADAMTS20 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867174791, COSV67126043; called by muse, mutect2
- ADAMTS3 | c.3194C>T p.A1065V | Missense Mutation (SNP) | VAF 81/305 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.08); catalogued as rs1298267630; called by muse, mutect2, varscan2
- ADAMTS3 | c.557G>T p.R186I | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV54394298, COSV99711647; called by muse, mutect2, varscan2
- ADAMTS5 | c.2482G>T p.E828* | Nonsense Mutation (SNP) | VAF 25/225 reads (11%) | catalogued as COSV99537889; called by muse, mutect2, varscan2
- ADAMTS7 | c.4427G>A p.R1476H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs773235448; called by mutect2, varscan2
- ADAMTS8 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.246); catalogued as rs1288941458, COSV57291815; called by muse, mutect2, varscan2
- ADAMTS9 | c.2486A>G p.Y829C | Missense Mutation (SNP) | VAF 55/440 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55780918; called by muse, mutect2, varscan2
- ADAMTSL1 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 46/444 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1473503207, COSV99444355; called by muse, mutect2
- ADAMTSL3 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 85/306 reads (28%) | catalogued as rs771154300, COSV99721988; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4159C>T p.R1387* | Nonsense Mutation (SNP) | VAF 13/148 reads (9%) | catalogued as rs1333944021, COSV54436494, COSV54474908; called by muse, mutect2
- ADAMTSL4 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 20/135 reads (15%) | catalogued as rs971960235; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1777G>A p.V593I | Missense Mutation (SNP) | VAF 65/530 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as rs757656099, COSV55009515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAR | c.3076C>T p.R1026W | Missense Mutation (SNP) | VAF 118/471 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs374300359, CM101655; called by muse, mutect2, varscan2
- ADAT1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777652272, COSV57186153; called by muse, mutect2, varscan2
- ADCK1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 34/256 reads (13%) | catalogued as COSV53086886; called by muse, mutect2, varscan2
- ADCK1 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs752581267, COSV53079235; called by muse, mutect2
- ADCY10 | c.2331G>T p.E777D | Missense Mutation (SNP) | VAF 63/469 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1384657472, COSV100896835; called by muse, mutect2, varscan2
- ADCY6 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as rs751987209; called by muse, mutect2, varscan2
- ADCY7 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202891173, COSV54264517; called by muse, mutect2
- ADCY8 | c.2630A>G p.Y877C | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as rs748482672; called by muse, mutect2, varscan2
- ADCY8 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs747184724; called by muse, mutect2, varscan2
- ADCY9 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53578500; called by muse, mutect2, varscan2
- ADD2 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 18/91 reads (20%) | catalogued as COSV100036774, COSV52455725; called by muse, mutect2, varscan2
- ADD2 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs782189292, COSV52465148; called by muse, mutect2
- ADGB | c.1040C>A p.S347Y | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1180645861; called by muse, varscan2
- ADGB | c.4595G>A p.R1532Q | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs746595057, COSV58852102; called by muse, varscan2
- ADGRA2 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs147459946, COSV100178112; called by muse, mutect2, varscan2
- ADGRA2 | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142650653; called by muse, varscan2
- ADGRA3 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51560602; called by muse, varscan2
- ADGRE1 | c.1646T>C p.I549T | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs530403566; called by mutect2, varscan2
- ADGRF4 | c.81G>T p.K27N | Missense Mutation (SNP) | VAF 77/268 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV51957874, COSV51958580; called by muse, mutect2, varscan2
- ADGRF5 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1399202712; called by muse, mutect2, varscan2
- ADGRG2 | c.2965G>A p.E989K (on ENST00000379869 / NM_001079858.3; = p.E986K on NM_005756.4) | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs1481978044; called by muse, mutect2, varscan2
- ADGRG2 | c.1784G>A p.R595K (on ENST00000379869 / NM_001079858.3; = p.R592K on NM_005756.4) | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1432545375, COSV61340169; called by muse, mutect2, varscan2
- ADGRG2 | c.562A>G p.T188A (on ENST00000379869 / NM_001079858.3; = p.T185A on NM_005756.4) | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.54); catalogued as rs756376191; called by muse, mutect2, varscan2
- ADGRG4 | c.2934C>A p.F978L | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV54952961; called by muse, mutect2, varscan2
- ADGRG4 | c.5045C>A p.S1682Y | Missense Mutation (SNP) | VAF 61/380 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV54949124; called by muse, mutect2, varscan2
- ADGRG4 | c.5974C>A p.L1992I | Missense Mutation (SNP) | VAF 134/362 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV54950689; called by muse, mutect2, varscan2
- ADGRL2 | c.2132-1G>A p.X711_splice (on ENST00000370717 / NM_001366005.1; = p.X698_splice on NM_012302.4) | Splice Site (SNP) | VAF 45/297 reads (15%) | catalogued as COSV54687095; called by muse, mutect2, varscan2
- ADGRL2 | c.2897G>A p.G966E (on ENST00000370717 / NM_001366005.1; = p.G953E on NM_012302.4) | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54665457, COSV99587647; called by muse, varscan2
- ADGRL2 | c.3280G>T p.E1094* (on ENST00000370717 / NM_001366005.1; = p.E1081* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 17/139 reads (12%) | catalogued as COSV54658988; called by muse, mutect2
- ADGRL3 | c.1252G>A p.D418N (on ENST00000506720 / NM_001322402.2; = p.D350N on NM_015236.6) | Missense Mutation (SNP) | VAF 42/371 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.777); catalogued as COSV72274430; called by muse, mutect2, varscan2
- ADGRL3 | c.1433C>A p.S478Y (on ENST00000506720 / NM_001322402.2; = p.S410Y on NM_015236.6) | Missense Mutation (SNP) | VAF 113/445 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV72267671, COSV72269295; called by muse, mutect2, varscan2
- ADGRL4 | c.1353C>A p.F451L | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV66062953; called by muse, varscan2
- ADGRL4 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs866442932, COSV66060786, COSV66063775; called by muse, varscan2
- ADGRV1 | c.1229G>T p.R410I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV67980057; called by muse, mutect2
- ADGRV1 | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771784301, CM135898, COSV67996767; called by muse, mutect2, varscan2
- ADGRV1 | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs762744741, COSV67980221; called by muse, mutect2, varscan2
- ADGRV1 | c.8680A>G p.I2894V | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.088); catalogued as rs538225155; called by muse, mutect2, varscan2
- ADGRV1 | c.9590T>C p.L3197S | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as rs727504685; ClinVar: uncertain significance; called by muse, mutect2
- ADH5 | c.1033T>G p.F345V | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56449344; called by muse, mutect2, varscan2
- ADH5 | c.900A>C p.E300D | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.817); catalogued as rs912381311; called by muse, mutect2, varscan2
- ADH7 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs201695257, COSV52919541; called by muse, mutect2, varscan2
- ADH7 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs759568380, COSV52920929; called by muse, varscan2
- ADORA2B | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs780529349, COSV58482827, COSV58483558; called by muse, varscan2
- ADPRH | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 96/679 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761010216, COSV63695476; called by muse, varscan2
- ADRB1 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756619440; called by muse, varscan2
- AFDN | c.2788C>T p.Q930* | Nonsense Mutation (SNP) | VAF 27/207 reads (13%) | catalogued as rs761425578; called by muse, mutect2, varscan2
- AFF3 | c.2990A>G p.K997R | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1316307633, COSV57841010; called by muse, mutect2, varscan2
- AFF3 | c.2082G>T p.Q694H | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100418831; called by muse, mutect2, varscan2
- AFF3 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs201587401, COSV100419579; called by muse, varscan2
- AFF4 | c.3178A>C p.K1060Q | Missense Mutation (SNP) | VAF 55/367 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as rs1331954655; called by muse, mutect2, varscan2
- AFG3L2 | c.1922G>T p.R641I | Missense Mutation (SNP) | VAF 103/746 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99301602; called by muse, mutect2, varscan2
- AFG3L2 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 81/594 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs776352499, COSV52312899; called by muse, mutect2, varscan2
- AFM | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 35/358 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs765807836, COSV56920480; called by muse, mutect2, varscan2
- AFMID | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs1428490787; called by muse, mutect2, varscan2
- AFP | c.434T>G p.V145G | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs556662592; called by muse, varscan2
- AFP | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 40/506 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV56923683; called by muse, mutect2
- AGAP1 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs969395658, COSV58320528; called by muse, mutect2, varscan2
- AGAP6 | c.1348A>G p.M450V (on ENST00000374056 / NM_001365867.1; = p.M473V on NM_001077665.2) | Missense Mutation (SNP) | VAF 73/933 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as rs782323010; called by muse, mutect2, varscan2
- AGBL1 | c.2076-1G>T p.X692_splice | Splice Site (SNP) | VAF 23/152 reads (15%) | catalogued as COSV101224141; called by muse, mutect2
- AGBL3 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as rs998810279; called by muse, mutect2
- AGFG1 | c.1307T>C p.F436S | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59511142; called by muse, mutect2, varscan2
- AGFG2 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.788); catalogued as rs776532327; called by muse, mutect2, varscan2
- AGO1 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs761121371, COSV100940896; called by muse, mutect2
- AGO3 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 43/497 reads (9%) | catalogued as COSV55796866; called by muse, mutect2
- AGO3 | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 38/338 reads (11%) | catalogued as COSV55792360; called by muse, mutect2, varscan2
- AGPAT1 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 111/473 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs1349120316, COSV61248802; called by muse, mutect2, varscan2
- AGRN | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 129/566 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.806); catalogued as rs753280577, COSV101038689, COSV65069859; called by muse, mutect2, varscan2
- AGRN | c.4811G>A p.R1604H | Missense Mutation (SNP) | VAF 67/444 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs772811721, COSV65069639; called by muse, mutect2, varscan2
- AGT | c.914G>T p.S305I | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV64185479; called by muse, mutect2, varscan2
- AGTRAP | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.033); catalogued as COSV100065409; called by muse, mutect2
- AHCTF1 | c.3727C>T p.R1243* (on ENST00000366508; = p.R1217* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 35/250 reads (14%) | catalogued as rs763622332, COSV58248284; called by muse, mutect2, varscan2
- AHCTF1 | c.363C>A p.F121L (on ENST00000366508; = p.F95L on NM_015446.5) | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV58246083; called by muse, mutect2, varscan2
- AHCYL1 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 62/290 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs750096391; called by muse, mutect2, varscan2
- AHCYL2 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 23/343 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.041); catalogued as rs1364013397; called by muse, mutect2
- AHNAK | c.16525G>A p.V5509M | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs780424012, COSV57236384; called by muse, varscan2
- AHNAK | c.12987C>A p.F4329L | Missense Mutation (SNP) | VAF 51/440 reads (12%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.981); catalogued as rs1162576710; called by muse, mutect2, varscan2
- AHNAK | c.12768G>T p.K4256N | Missense Mutation (SNP) | VAF 66/432 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV99946418; called by muse, mutect2, varscan2
- AHNAK2 | c.14888T>G p.F4963C | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60922298; called by muse, mutect2, varscan2
- AHNAK2 | c.8311G>A p.D2771N | Missense Mutation (SNP) | VAF 87/575 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as rs1222176163; called by muse, mutect2, varscan2
- AHNAK2 | c.2025C>A p.F675L | Missense Mutation (SNP) | VAF 156/636 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV60911848; called by muse, varscan2
- AHNAK2 | c.1873G>T p.E625* | Nonsense Mutation (SNP) | VAF 140/502 reads (28%) | catalogued as COSV60927359; called by muse, varscan2
- AIDA | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.974); catalogued as rs1472689471, COSV60664703; called by muse, mutect2, varscan2
- AIFM3 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748492260; called by muse, mutect2, varscan2
- AK9 | c.3539A>C p.K1180T | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs755288597; called by muse, varscan2
- AK9 | c.1682A>G p.Y561C | Missense Mutation (SNP) | VAF 108/282 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as COSV58150627; called by muse, mutect2, varscan2
- AKAP1 | c.68G>A p.W23* | Nonsense Mutation (SNP) | VAF 59/448 reads (13%) | catalogued as COSV58469516; called by muse, mutect2, varscan2
- AKAP11 | c.4286G>T p.R1429I | Missense Mutation (SNP) | VAF 55/391 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1308479533, COSV50293081; called by muse, mutect2, varscan2
- AKAP13 | c.479-1G>A p.X160_splice | Splice Site (SNP) | VAF 13/108 reads (12%) | catalogued as COSV63450525; called by muse, mutect2, varscan2
- AKAP13 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs779495573, COSV100773513; called by muse, mutect2, varscan2
- AKAP17A | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 19/324 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.762); catalogued as rs1264082692; called by muse, mutect2
- AKAP5 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs750967463, COSV57742270; called by muse, mutect2, varscan2
- AKAP6 | c.6147A>C p.K2049N | Missense Mutation (SNP) | VAF 103/376 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs772586515, COSV55237451; called by muse, mutect2, varscan2
- AKAP8L | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs576284598; called by muse, mutect2, varscan2
- AKAP9 | c.3139A>C p.K1047Q | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV62342524; called by muse, varscan2
- AKNAD1 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV62194479; called by muse, varscan2
- AKNAD1 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 32/376 reads (9%) | catalogued as COSV62198085; called by muse, mutect2
- AKR1A1 | c.826-4T>G | Splice Region (SNP) | VAF 104/345 reads (30%) | catalogued as rs1409224225; called by muse, mutect2, varscan2
- AKT1S1 | c.626C>T p.P209L (on ENST00000344175 / NM_001098633.4; = p.P229L on NM_032375.5) | Missense Mutation (SNP) | VAF 93/388 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs747800150, COSV59276551; called by muse, mutect2, varscan2
- AKT3 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 31/252 reads (12%) | catalogued as COSV55612501, COSV99796232; called by muse, mutect2, varscan2
- AKTIP | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs1394013364, COSV100043254; called by muse, mutect2, varscan2
- AL133500.1 | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT deleterious, low confidence (0); catalogued as rs760475507, COSV99860513; called by muse, varscan2
- AL645922.1 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 68/706 reads (10%) | catalogued as rs763450579, COSV54962560; called by muse, mutect2
- ALAS2 | c.1265C>A p.S422Y | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100238284, COSV58193160; called by muse, mutect2, varscan2
- ALB | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 140/490 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs138715514, COSV55740561; called by muse, mutect2, varscan2
- ALB | c.1194C>T p.F398= | Splice Region (SNP) | VAF 45/326 reads (14%) | catalogued as rs770952660, COSV55735522, COSV55737469; ClinVar: uncertain significance; called by muse, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 131/492 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by muse, mutect2, varscan2
- ALDH1B1 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs1178997279; called by muse, mutect2
- ALDH4A1 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 87/641 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs780298027; called by muse, mutect2, varscan2
- ALDH5A1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 98/770 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62373245; called by muse, varscan2
- ALDOB | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 82/703 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV66398368, COSV66399024; called by muse, mutect2, varscan2
- ALG11 | c.1063A>G p.N355D | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV101584233; called by muse, mutect2
- ALG12 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 48/278 reads (17%) | PolyPhen benign (0.015); catalogued as rs578038511, COSV58206720; called by muse, mutect2, varscan2
- ALG13 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 34/272 reads (13%) | catalogued as COSV52638289; called by muse, mutect2, varscan2
- ALG13 | c.3355C>T p.P1119S | Missense Mutation (SNP) | VAF 36/331 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV52635017; called by muse, mutect2, varscan2
- ALG3 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375976807; called by muse, mutect2
- ALG5 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV53505210; called by muse, mutect2, varscan2
- ALKBH8 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 55/448 reads (12%) | catalogued as COSV52836941; called by muse, mutect2, varscan2
- ALMS1 | c.7226C>T p.T2409I | Missense Mutation (SNP) | VAF 80/495 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866357733, COSV52517136; called by muse, mutect2, varscan2
- ALMS1 | c.9673C>T p.R3225C | Missense Mutation (SNP) | VAF 46/578 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs200215551; ClinVar: uncertain significance; called by muse, mutect2
- ALOX12B | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 84/556 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs368425810; called by muse, mutect2, varscan2
- ALOX5 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs989659749, COSV65551915; called by muse, mutect2, varscan2
- ALOX5AP | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs776630925, COSV100996268, COSV66857642; called by muse, mutect2, varscan2
- ALPG | c.879G>T p.M293I | Missense Mutation (SNP) | VAF 62/507 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99779120; called by muse, varscan2
- ALPI | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 56/397 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs753905708, COSV55015387, COSV55016013; called by muse, mutect2, varscan2
- ALPK1 | c.3140G>T p.R1047I | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51591269; called by muse, varscan2
- ALPK2 | c.5792G>A p.R1931H | Missense Mutation (SNP) | VAF 57/512 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1221185165, COSV64492761; called by muse, mutect2, varscan2
- ALPK2 | c.3949G>A p.E1317K | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs771196152, COSV64496773; called by muse, varscan2
- ALPK2 | c.3934G>T p.E1312* | Nonsense Mutation (SNP) | VAF 30/232 reads (13%) | catalogued as COSV64494797; called by muse, varscan2
- ALPK2 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 52/426 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV64493298; called by muse, varscan2
- ALS2 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 109/805 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1309144602, COSV51887988; called by muse, mutect2, varscan2
- ALS2 | c.2495T>C p.I832T | Missense Mutation (SNP) | VAF 130/452 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1319168361; called by muse, varscan2
- ALS2CL | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs149519981; called by muse, mutect2, varscan2
- ALX4 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 118/364 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as rs768153687, COSV100241118, COSV61327672; called by muse, varscan2
- AMACR | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201507169, COSV56871888; called by muse, varscan2
- AMBN | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774473809, COSV100534483, COSV59827087; called by muse, varscan2
- AMBP | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768762324; called by muse, varscan2
- AMELX | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 83/678 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs367556910, COSV61631109; called by muse, mutect2, varscan2
- AMER3 | c.191G>T p.R64I | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1297298563, COSV58466791; called by muse, mutect2, varscan2
- AMFR | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 42/434 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV51920352; called by muse, mutect2
- AMH | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs375971454; called by muse, mutect2, varscan2
- AMIGO2 | c.640T>G p.L214V | Missense Mutation (SNP) | VAF 96/364 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs750585684; called by muse, mutect2, varscan2
- AMIGO3 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 83/614 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1237596292, COSV57539411; called by muse, mutect2, varscan2
- AMIGO3 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.258); catalogued as COSV104404532; called by muse, mutect2, varscan2
- AMOTL1 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1161931337, COSV58565831; called by muse, mutect2, varscan2
- AMPD1 | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 71/595 reads (12%) | catalogued as COSV62419010; called by muse, mutect2, varscan2
- AMY2A | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 70/654 reads (11%) | catalogued as rs566657194; called by muse, varscan2
- AMY2B | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 57/455 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140146360; called by muse, mutect2, varscan2
- AMY2B | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 59/585 reads (10%) | catalogued as rs377067814, COSV63714132; called by muse, mutect2, varscan2
- ANAPC1 | c.4619G>A p.R1540H | Missense Mutation (SNP) | VAF 42/452 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1237878656; called by muse, varscan2
- ANAPC1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs137965758, COSV61974781; called by muse, mutect2, varscan2
- ANAPC15 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 115/472 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); catalogued as rs982888986, COSV56191427; called by muse, mutect2, varscan2
- ANAPC4 | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 124/477 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs919120354; called by muse, mutect2, varscan2
- ANAPC5 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 56/597 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs755699638; called by muse, mutect2
- ANGPTL3 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756641927; called by muse, mutect2, varscan2
- ANGPTL5 | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.037); catalogued as rs778018097; called by muse, varscan2
- ANK1 | c.4906G>A p.D1636N | Missense Mutation (SNP) | VAF 94/664 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.3); catalogued as rs757733100, COSV99227134; called by muse, mutect2, varscan2
- ANK1 | c.4307G>A p.R1436Q | Missense Mutation (SNP) | VAF 114/811 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs1460910760, COSV55878923; called by muse, varscan2
- ANK1 | c.2723C>T p.P908L | Missense Mutation (SNP) | VAF 96/741 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs146518198, COSV99224772; called by muse, mutect2, varscan2
- ANK2 | c.5588C>T p.T1863M | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs536962908, COSV52152126; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.9391T>A p.F3131I | Missense Mutation (SNP) | VAF 54/856 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52154720; called by muse, mutect2
- ANK2 | c.11153C>A p.S3718Y | Missense Mutation (SNP) | VAF 73/614 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52176132; called by muse, mutect2, varscan2
- ANK3 | c.5237C>A p.S1746Y | Missense Mutation (SNP) | VAF 46/489 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.204); catalogued as rs754173928, COSV55071553, COSV55072795; called by muse, mutect2
- ANK3 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 95/351 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs139879505; called by muse, mutect2, varscan2
- ANKFY1 | c.2966G>A p.R989Q (on ENST00000341657 / NM_001330063.2; = p.R990Q on NM_016376.5) | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs760267257; called by muse, mutect2, varscan2
- ANKH | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 98/644 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs947608393; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99784314; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.6406C>T p.R2136* | Nonsense Mutation (SNP) | VAF 57/471 reads (12%) | catalogued as COSV51846169; called by muse, mutect2, varscan2
- ANKLE2 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs761627940, COSV61709114; called by muse, mutect2, varscan2
- ANKMY1 | c.2344G>A p.V782M | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238657319; called by muse, mutect2, varscan2
- ANKMY1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56031964; called by muse, mutect2, varscan2
- ANKMY1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 68/521 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56034311; called by muse, varscan2
- ANKRD12 | c.3764C>A p.S1255Y | Missense Mutation (SNP) | VAF 54/511 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50847464; called by muse, mutect2, varscan2
- ANKRD12 | c.4162C>T p.L1388F | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.042); catalogued as COSV50819429, COSV50823705; called by muse, mutect2, varscan2
- ANKRD12 | c.4900G>T p.E1634* | Nonsense Mutation (SNP) | VAF 55/352 reads (16%) | catalogued as COSV100042288, COSV104383076; called by muse, mutect2, varscan2
- ANKRD13B | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1465096584; called by muse, mutect2, varscan2
- ANKRD17 | c.6392C>T p.P2131L | Missense Mutation (SNP) | VAF 200/722 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs749174957, COSV58222630; called by muse, mutect2, varscan2
- ANKRD18A | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs866752033, COSV57632718; called by muse, mutect2, varscan2
- ANKRD18B | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as COSV52087590; called by muse, mutect2, varscan2
- ANKRD2 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 65/318 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs765534840; called by muse, mutect2, varscan2
- ANKRD20A1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs768986280; called by muse, varscan2
- ANKRD22 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs559515763, COSV64236039; called by muse, mutect2, varscan2
- ANKRD24 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 67/566 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as rs754294178; called by muse, mutect2, varscan2
- ANKRD26 | c.4703C>A p.S1568Y | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101062889; called by muse, mutect2
- ANKRD26 | c.3265G>T p.E1089* | Nonsense Mutation (SNP) | VAF 19/265 reads (7%) | catalogued as COSV101062840, COSV65776214; called by muse, mutect2
- ANKRD26 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 79/590 reads (13%) | catalogued as COSV65775303; called by muse, varscan2
- ANKRD26 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as rs370689749; called by muse, mutect2, varscan2
- ANKRD30A | c.3235G>T p.E1079* (on ENST00000611781; = p.E1023* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 44/190 reads (23%) | catalogued as COSV64613134; called by muse, varscan2
- ANKRD30B | c.2639C>A p.S880Y | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.316); catalogued as rs570993169; called by muse, mutect2, varscan2
- ANKRD36 | c.195A>G p.E65= | Splice Region (SNP) | VAF 70/492 reads (14%) | catalogued as COSV101347560; called by muse, mutect2, varscan2
- ANKRD36 | c.3354A>C p.E1118D | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs1305826231; called by muse, mutect2
- ANKRD36C | c.3719G>T p.C1240F | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.205); catalogued as COSV69432839; called by muse, mutect2, varscan2
- ANKRD44 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs750473345, COSV99985292; called by muse, mutect2, varscan2
- ANKRD50 | c.4021C>T p.R1341* | Nonsense Mutation (SNP) | VAF 112/409 reads (27%) | catalogued as rs1560816656, COSV72385946, COSV72386359; called by muse, mutect2, varscan2
- ANKRD62 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1186904272; called by muse, varscan2
- ANKS1A | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs757275006, COSV64462795; called by muse, mutect2, varscan2
- ANKS1B | c.3661C>T p.R1221C (on ENST00000547776 / NM_152788.4; = p.R387C on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs867103953, COSV59116554; called by muse, mutect2
- ANKS4B | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61140489; called by muse, mutect2, varscan2
- ANKS6 | c.2147T>C p.L716S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.335); catalogued as rs1564189869; called by muse, mutect2, varscan2
- ANKS6 | c.2029G>A p.G677R | Missense Mutation (SNP) | VAF 58/403 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs761669977; called by muse, mutect2, varscan2
- ANLN | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373587417; called by muse, mutect2, varscan2
- ANO1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs199526216; called by muse, mutect2, varscan2
- ANO1 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 100/328 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as rs200119718; called by muse, mutect2, varscan2
- ANO1 | c.2349C>T p.I783= | Splice Region (SNP) | VAF 20/148 reads (14%) | catalogued as rs748584110, COSV62449147; called by muse, mutect2
- ANO4 | c.839T>G p.I280S (on ENST00000392977 / NM_001286615.2; = p.I245S on NM_178826.4) | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs375891394; called by muse, varscan2
- ANO7 | c.266C>T p.S89L (on ENST00000274979; = p.S35L on NM_001001666.4) | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs866019321; called by muse, mutect2, varscan2
- ANO7 | c.445C>T p.R149C (on ENST00000274979; = p.R94C on NM_001001666.4) | Missense Mutation (SNP) | VAF 180/531 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs763945681, COSV51467841; called by muse, mutect2, varscan2
- ANO7 | c.2590G>A p.V864I (on ENST00000274979; = p.V810I on NM_001370694.2) | Missense Mutation (SNP) | VAF 39/352 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368164427; called by muse, mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 54/650 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, mutect2
- ANP32A | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 73/669 reads (11%) | catalogued as COSV51189738; called by muse, mutect2, varscan2
- ANTXR2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.677); catalogued as rs756324499, COSV56313262; called by muse, varscan2
- ANTXRL | c.836A>T p.N279I | Missense Mutation (SNP) | VAF 82/329 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1565029132; called by muse, varscan2
- ANXA1 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 30/295 reads (10%) | catalogued as rs756648223, COSV57411924, COSV57412216; called by muse, mutect2, varscan2
- ANXA13 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 58/486 reads (12%) | catalogued as COSV51626956; called by muse, varscan2
- ANXA13 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 60/405 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51625215; called by muse, mutect2, varscan2
- ANXA5 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs141889791, COSV56638767; called by muse, mutect2, varscan2
- ANXA6 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1177861653, COSV62905807; called by muse, mutect2
- AOC2 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 90/633 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764589106; called by muse, mutect2, varscan2
- AOX1 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 34/194 reads (18%) | catalogued as rs754596150, COSV65981094; called by muse, mutect2, varscan2
- AOX1 | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV65982843; called by muse, varscan2
- AP1G2 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as rs779527662; called by muse, mutect2, varscan2
- AP2A2 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1456413014, COSV100173296; called by muse, mutect2, varscan2
- AP4B1 | c.935G>T p.S312I | Missense Mutation (SNP) | VAF 71/571 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs556275015; called by muse, mutect2, varscan2
- AP4E1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 102/450 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375514846; called by muse, mutect2, varscan2
- AP4E1 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs754437475, COSV55916257; called by muse, varscan2
- APAF1 | c.1283G>A p.R428Q (on ENST00000551964 / NM_181861.2; = p.R417Q on NM_001160.3) | Missense Mutation (SNP) | VAF 49/318 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.332); catalogued as rs1263053370; called by muse, mutect2, varscan2
- APBA2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.311); catalogued as rs1379131912, COSV101381803, COSV68792774, COSV68795881; called by muse, mutect2, varscan2
- APC | c.3566C>A p.S1189* | Nonsense Mutation (SNP) | VAF 75/634 reads (12%) | catalogued as COSV57334822, COSV57368194; called by muse, mutect2, varscan2
- APC | c.8401C>T p.R2801W | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1242407699, COSV99970654; ClinVar: uncertain significance; called by muse, varscan2
- APEH | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 120/452 reads (27%) | catalogued as rs577640330, COSV56517850; called by muse, mutect2, varscan2
- APEX1 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 55/460 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs778999137, COSV51658617; called by muse, mutect2, varscan2
- APEX1 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 68/565 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.653); catalogued as rs148298598, COSV99164520; called by muse, mutect2, varscan2
- APEX2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755988566; called by muse, mutect2, varscan2
- API5 | c.1324T>A p.S442T | Missense Mutation (SNP) | VAF 48/472 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66633794; called by muse, mutect2, varscan2
- APLP2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 54/494 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs765804148; called by muse, mutect2, varscan2
- APOB | c.12322C>A p.L4108M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.923); catalogued as rs1357281301, COSV51926540; called by muse, mutect2, varscan2
- APOB | c.11462C>T p.T3821I | Missense Mutation (SNP) | VAF 69/545 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs766891285; called by muse, mutect2, varscan2
- APOB | c.8597C>T p.T2866I | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs1208093663; called by muse, mutect2, varscan2
- APOB | c.4255A>G p.T1419A | Missense Mutation (SNP) | VAF 35/371 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV51941232, COSV99266685; called by muse, mutect2
- APOB | c.2605-1G>T p.X869_splice | Splice Site (SNP) | VAF 50/419 reads (12%) | catalogued as COSV51926377; called by muse, mutect2, varscan2
- APOBEC3D | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs765992781; called by mutect2, varscan2
- APOBEC3G | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.281); catalogued as rs1172899083; called by muse, mutect2, varscan2
- APOBEC3H | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV62378548; called by muse, mutect2
- APOBEC4 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs750282103; called by muse, varscan2
- APPL2 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 119/442 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1032902795, COSV51589391; called by muse, mutect2, varscan2
- AQP1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.129); catalogued as rs761409742; called by muse, mutect2, varscan2
- AQP2 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 96/528 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1206293615, COSV52231795; called by muse, mutect2, varscan2
- AQP3 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 75/617 reads (12%) | SIFT tolerated (0.57); PolyPhen probably damaging (1); catalogued as rs777633399, COSV99955439; called by muse, mutect2, varscan2
- AQP4 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 225/846 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs528517012, COSV67218235; called by muse, mutect2, varscan2
- AQP7 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 70/469 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV53027732; called by muse, mutect2, varscan2
- AQR | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1256597416, COSV99334979; called by muse, varscan2
- AQR | c.2821A>G p.M941V | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1181128383; called by muse, varscan2
- ARAP2 | c.2999A>G p.K1000R | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1233247869; called by muse, mutect2, varscan2
- ARAP3 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53348533; called by muse, mutect2, varscan2
- ARCN1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 35/347 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1555076137, COSV50616086; called by muse, mutect2
- AREL1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 86/646 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.861); catalogued as rs766118763, COSV62667136; called by muse, mutect2, varscan2
- ARF1 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV55255981; called by muse, mutect2, varscan2
- ARF4 | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 34/417 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV57714666, COSV57715913; called by muse, mutect2
- ARFGEF1 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51602923; called by muse, varscan2
- ARFGEF1 | c.1750A>C p.N584H | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV51612991; called by muse, mutect2, varscan2
- ARFGEF2 | c.1475C>A p.S492Y | Missense Mutation (SNP) | VAF 222/815 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64211331, COSV64213467; called by muse, mutect2, varscan2
- ARFGEF3 | c.4237A>C p.I1413L | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV52470807; called by muse, varscan2
- ARFGEF3 | c.6262C>T p.R2088* | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | catalogued as rs1281263362, COSV52452202, COSV52457190; called by muse, mutect2
- ARHGAP1 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770134284; called by muse, mutect2, varscan2
- ARHGAP10 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs145234400; called by mutect2, varscan2
- ARHGAP10 | c.2340G>T p.Q780H | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs975335551; called by muse, mutect2, varscan2
- ARHGAP12 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs369473115; called by muse, mutect2
- ARHGAP12 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs913388274; called by muse, mutect2
- ARHGAP15 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV99713592; called by muse, mutect2
- ARHGAP18 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 60/436 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV104426853; called by muse, mutect2, varscan2
- ARHGAP19 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs771390013, COSV57393724; called by muse, mutect2, varscan2
- ARHGAP21 | c.4454C>T p.T1485M | Missense Mutation (SNP) | VAF 137/508 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.238); catalogued as rs569426222, COSV57603820; called by muse, mutect2, varscan2
- ARHGAP21 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57605752; called by muse, varscan2
- ARHGAP21 | c.1569dup p.Q524Tfs*10 | Frame Shift Ins (INS) | VAF 38/309 reads (12%) | catalogued as rs1565032132; called by mutect2, pindel, varscan2
- ARHGAP22 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200717294; called by muse, varscan2
- ARHGAP22 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV50963896, COSV50988110; called by muse, mutect2, varscan2
- ARHGAP26 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749597249, COSV50828807; called by muse, mutect2, varscan2
- ARHGAP26 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs760497830, COSV50829906; called by muse, mutect2, varscan2
- ARHGAP32 | c.2024G>A p.R675Q (on ENST00000310343 / NM_001378025.1; = p.R326Q on NM_014715.4) | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs141414658; called by muse, mutect2, varscan2
- ARHGAP32 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs776079368, COSV59845539; called by muse, mutect2, varscan2
- ARHGAP35 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 87/582 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs778118639, COSV101351570; called by muse, mutect2, varscan2
- ARHGAP35 | c.2014T>C p.S672P | Missense Mutation (SNP) | VAF 31/389 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as COSV68332869; called by muse, mutect2
- ARHGAP36 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 24/165 reads (15%) | catalogued as COSV52265620; called by muse, mutect2, varscan2
- ARHGAP42 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 37/281 reads (13%) | catalogued as COSV53989297; called by muse, mutect2, varscan2
- ARHGAP45 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1481803053; called by muse, mutect2, varscan2
- ARHGAP5 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as rs757199082, COSV61538712; called by muse, mutect2, varscan2
- ARHGAP6 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 55/401 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV57294838; called by muse, mutect2, varscan2
- ARHGAP6 | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 39/341 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV104399443; called by muse, mutect2, varscan2
- ARHGAP6 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.84); catalogued as rs766331432, COSV61625847; called by muse, varscan2
- ARHGDIG | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537147515; called by muse, mutect2, varscan2
- ARHGEF10 | c.863C>T p.S288L (on ENST00000398564; = p.S263L on NM_014629.4) | Missense Mutation (SNP) | VAF 67/478 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs775934719, COSV100033327; called by muse, mutect2, varscan2
- ARHGEF10 | c.1658G>A p.R553Q (on ENST00000398564; = p.R528Q on NM_014629.4) | Missense Mutation (SNP) | VAF 87/582 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143325951; called by muse, mutect2, varscan2
- ARHGEF10 | c.1928G>A p.R643Q (on ENST00000398564; = p.R618Q on NM_014629.4) | Missense Mutation (SNP) | VAF 105/428 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); catalogued as rs1349820120; called by muse, mutect2, varscan2
- ARHGEF11 | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1259740199; called by muse, mutect2
- ARHGEF11 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1388884489, CM142294, COSV100168393; called by muse, mutect2
- ARHGEF12 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 88/340 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483560417; called by muse, varscan2
- ARHGEF17 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs769100884, COSV55230794; called by muse, mutect2, varscan2
- ARHGEF17 | c.3788G>A p.R1263H | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs747501115; called by muse, mutect2, varscan2
- ARHGEF26 | c.1713G>A p.M571I | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100726377; called by muse, varscan2
- ARHGEF28 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55255404; called by muse, mutect2
- ARID1A | c.5636G>A p.R1879Q | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs371595717; called by muse, varscan2
- ARID1B | c.6599C>T p.S2200L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as rs1379093164, COSV51666580; called by muse, varscan2
- ARID2 | c.2969C>T p.S990L | Missense Mutation (SNP) | VAF 67/418 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.163); catalogued as rs758368727, COSV57604758; called by muse, mutect2, varscan2
- ARID4A | c.3565C>A p.L1189I | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100794356; called by muse, mutect2, varscan2
- ARID4B | c.3086C>T p.S1029L | Missense Mutation (SNP) | VAF 53/503 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs766055448; called by muse, varscan2
- ARID5A | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs774151096; called by muse, mutect2, varscan2
- ARID5B | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.206); catalogued as COSV54418430; called by muse, mutect2, varscan2
- ARID5B | c.3410C>A p.S1137Y | Missense Mutation (SNP) | VAF 105/329 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99689472; called by muse, mutect2, varscan2
- ARL4A | c.449T>G p.L150W | Missense Mutation (SNP) | VAF 65/374 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs1369786817; called by muse, varscan2
- ARL4A | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs752253129; called by muse, varscan2
- ARL5A | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1215342829; called by muse, mutect2, varscan2
- ARL5B | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs372696681; called by muse, mutect2, varscan2
- ARMC12 | c.466G>A p.E156K (on ENST00000373866 / NM_001286574.2; = p.E183K on NM_145028.5) | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs148096096; called by muse, mutect2, varscan2
- ARMC4 | c.2688A>C p.E896D | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV59470786; called by muse, mutect2, varscan2
- ARMC5 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs1252478434; called by muse, mutect2
- ARMCX2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs782242885, COSV57530775; called by muse, mutect2, varscan2
- ARMCX2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs781812794, COSV57529190; called by muse, mutect2
- ARNT2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211454281, COSV100308950; called by muse, mutect2
- ARNT2 | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV57583786; called by muse, mutect2
- ARNTL | c.1189G>T p.E397* (on ENST00000403290 / NM_001297719.2; = p.E396* on NM_001178.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV62985016; called by muse, mutect2
- ARPC2 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV55283588; called by muse, mutect2, varscan2
- ARPC5L | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as rs771650589, COSV52346848; called by muse, mutect2
- ARRDC4 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.616); catalogued as rs1262150973; called by muse, mutect2, varscan2
- ARRDC5 | c.995G>A p.G332E (on ENST00000381781; = p.G318E on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV101108291; called by muse, varscan2
- ARSL | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 108/852 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.42); catalogued as rs752659017; called by muse, mutect2, varscan2
- ART3 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs755477316; called by muse, mutect2, varscan2
- ART4 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV57451851; called by muse, varscan2
- ASAP2 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 61/416 reads (15%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.975); catalogued as rs919010572, COSV55634729, COSV55636496; called by muse, mutect2, varscan2
- ASB1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs376136799; called by muse, mutect2, varscan2
- ASB10 | c.811G>A p.A271T (on ENST00000420175 / NM_001142459.2; = p.A256T on NM_080871.4) | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs762991342, COSV52001492; called by muse, mutect2
- ASB11 | c.68dup p.F24Lfs*2 | Frame Shift Ins (INS) | VAF 22/150 reads (15%) | catalogued as rs770804405; called by mutect2, varscan2
- ASB15 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs1224190284; called by muse, varscan2
- ASB15 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 113/289 reads (39%) | catalogued as rs1237485684, COSV51923543; called by muse, mutect2, varscan2
- ASB2 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 48/365 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs372274381, COSV100279170; called by muse, mutect2, varscan2
- ASB4 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 61/395 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV57944061; called by muse, mutect2, varscan2
- ASB4 | c.1013T>C p.I338T | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs754354081; called by muse, varscan2
- ASB5 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1331480430, COSV56669005; called by muse, mutect2, varscan2
- ASCC3 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 139/338 reads (41%) | catalogued as rs760927168, COSV64973923, COSV64977816; called by muse, mutect2, varscan2
- ASCC3 | c.3809G>A p.R1270Q | Missense Mutation (SNP) | VAF 131/605 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs778373627; called by muse, varscan2
- ASCC3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs138861677, COSV100225520; called by muse, varscan2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 103/343 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, mutect2, varscan2
- ASF1B | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs758936633; called by muse, mutect2, varscan2
- ASH1L | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 49/577 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs1416735817, COSV64207287; called by muse, mutect2
- ASIC4 | c.1375A>G p.R459G (on ENST00000347842 / NM_182847.3; = p.R478G on NM_018674.6) | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.16); catalogued as rs1432985529; called by muse, varscan2
- ASMT | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 70/538 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as rs779785578; called by muse, mutect2, varscan2
- ASPH | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 30/201 reads (15%) | catalogued as rs773987662, COSV101063530; called by muse, mutect2, varscan2
- ASPH | c.1907G>T p.R636I | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV65243759; called by muse, mutect2
- ASPM | c.7958C>A p.S2653Y | Missense Mutation (SNP) | VAF 114/688 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.484); catalogued as COSV54126632; called by muse, mutect2, varscan2
- ASPM | c.7215G>T p.K2405N | Missense Mutation (SNP) | VAF 71/612 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99660881; called by muse, varscan2
- ASPSCR1 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757210501, COSV60731519; called by mutect2, varscan2
- ASTE1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 172/624 reads (28%) | catalogued as rs773437504, COSV53909044; called by muse, mutect2, varscan2
- ASTL | c.282G>T p.W94C | Missense Mutation (SNP) | VAF 51/454 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV60905273; called by muse, mutect2, varscan2
- ASTN2 | c.2183C>T p.S728L (on ENST00000313400 / NM_001365069.1; = p.S677L on NM_014010.5) | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144736118; called by muse, mutect2, varscan2
- ASXL2 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV55465998; called by muse, mutect2, varscan2
- ASXL3 | c.3563C>A p.P1188Q | Missense Mutation (SNP) | VAF 105/337 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV99325343; called by muse, mutect2, varscan2
- ATAD2 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs772123752; called by muse, mutect2, varscan2
- ATAD2 | c.3307G>T p.E1103* | Nonsense Mutation (SNP) | VAF 40/140 reads (29%) | catalogued as COSV99784605; called by muse, mutect2, varscan2
- ATAD2 | c.1957C>T p.R653* | Nonsense Mutation (SNP) | VAF 80/240 reads (33%) | catalogued as rs1343284558, COSV54879452; called by muse, mutect2, varscan2
- ATAD2B | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV53204384; called by muse, mutect2
- ATAD2B | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 69/186 reads (37%) | catalogued as rs1315732917; called by muse, varscan2
- ATAD5 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV58974208; called by muse, mutect2, varscan2
- ATAD5 | c.4869G>T p.K1623N | Missense Mutation (SNP) | VAF 98/268 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as COSV100430263; called by muse, varscan2
- ATF6 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs145066726; called by muse, mutect2
- ATF7IP2 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 59/346 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1361151528, COSV61092378, COSV61095454; called by muse, varscan2
- ATG101 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 73/504 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1465612076, COSV61085321; called by muse, mutect2, varscan2
- ATG13 | c.1090G>A p.D364N (on ENST00000359513 / NM_001346321.1; = p.D327N on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs373152510; called by mutect2, varscan2
- ATG16L1 | c.1447C>T p.R483* (on ENST00000392017 / NM_030803.7; = p.R464* on NM_017974.4) | Nonsense Mutation (SNP) | VAF 31/199 reads (16%) | catalogued as COSV100731192; called by muse, mutect2, varscan2
- ATG2A | c.3923C>T p.A1308V | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs778490650; called by muse, mutect2, varscan2
- ATG2A | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 53/375 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs1427618972; called by muse, mutect2, varscan2
- ATG4A | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.935); catalogued as COSV57866597, COSV57872599; called by muse, mutect2, varscan2
- ATG4B | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as rs1196182391; called by muse, mutect2, varscan2
- ATG9B | c.1679C>T p.T560I | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1156355914; called by muse, mutect2, varscan2
- ATL1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 50/533 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs976793999, COSV63296138; called by muse, mutect2
- ATL1 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV61205833; called by muse, mutect2
- ATM | c.3153+2T>C p.X1051_splice | Splice Site (SNP) | VAF 57/556 reads (10%) | catalogued as COSV53764179; called by muse, mutect2, varscan2
- ATM | c.8419-1G>A p.X2807_splice | Splice Site (SNP) | VAF 28/250 reads (11%) | catalogued as COSV53748170, COSV53783047, COSV99589486; called by muse, mutect2, varscan2
- ATOX1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1026147447; called by muse, mutect2, varscan2
- ATP10A | c.728T>C p.F243S | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63518177; called by muse, mutect2
- ATP10A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 105/489 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV63512994; called by muse, varscan2
- ATP10D | c.472A>G p.K158E | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.105); catalogued as rs775214799; called by muse, mutect2, varscan2
- ATP10D | c.4148T>G p.F1383C | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.088); catalogued as COSV56687202; called by muse, mutect2, varscan2
- ATP11A | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV52111679; called by muse, mutect2
- ATP11B | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 82/330 reads (25%) | catalogued as rs1295948091, COSV60026923; called by muse, varscan2
- ATP11C | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV59564605; called by muse, mutect2, varscan2
- ATP13A1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 107/377 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1384614035; called by muse, mutect2, varscan2
- ATP13A2 | c.3457C>T p.R1153W | Missense Mutation (SNP) | VAF 78/508 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1197349768; called by muse, mutect2, varscan2
- ATP13A2 | c.2899G>A p.D967N | Missense Mutation (SNP) | VAF 85/641 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772870846; called by muse, varscan2
- ATP13A2 | c.1906C>T p.R636C | Missense Mutation (SNP) | VAF 126/473 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1236601412; called by muse, mutect2, varscan2
- ATP13A2 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 30/772 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs1213129765; called by muse, mutect2
- ATP13A5 | c.3406C>A p.L1136I | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.085); catalogued as COSV53232536; called by muse, varscan2
- ATP13A5 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as rs779728956, COSV60873919; called by muse, mutect2, varscan2
- ATP1A2 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 156/596 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs767672945; called by muse, mutect2, varscan2
- ATP1B1 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 78/463 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs781025471, COSV63164864; called by muse, varscan2
- ATP1B4 | c.839G>A p.R280Q (on ENST00000218008 / NM_001142447.3; = p.R276Q on NM_012069.5) | Missense Mutation (SNP) | VAF 33/337 reads (10%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.717); catalogued as rs763388319, COSV54312768, COSV54314743; called by muse, varscan2
- ATP2A1 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as rs142195151; called by muse, mutect2
- ATP2A2 | c.1915G>A p.G639S | Missense Mutation (SNP) | VAF 82/613 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs532508915, COSV57875650; called by muse, varscan2
- ATP2C1 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV67851383; called by muse, mutect2
- ATP2C1 | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 147/490 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs767996194; called by muse, mutect2, varscan2
- ATP2C1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs905995238, CM154426, COSV60752853, COSV60762794; called by muse, mutect2, varscan2
- ATP2C1 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 29/570 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60755007; called by muse, mutect2
- ATP5F1A | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as rs778135381; called by muse, mutect2, varscan2
- ATP6V0A2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 60/515 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs769927427, COSV57747972; called by muse, mutect2, varscan2
- ATP6V0A4 | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV59474144; called by muse, varscan2
- ATP6V1E1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1191953761, COSV53657009, COSV99494162; called by muse, mutect2, varscan2
- ATP6V1E2 | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as rs1209263048; called by muse, mutect2
- ATP6V1H | c.991A>G p.I331V | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as rs1319508395; called by muse, mutect2, varscan2
- ATP6V1H | c.123G>T p.M41I | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV62216766; called by muse, mutect2, varscan2
- ATP7B | c.2906G>T p.R969L | Missense Mutation (SNP) | VAF 70/532 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM950116; called by muse, varscan2
- ATP7B | c.1958C>A p.S653Y | Missense Mutation (SNP) | VAF 76/499 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM053794; called by muse, mutect2, varscan2
- ATP8A2 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.218); catalogued as rs1364473166; called by muse, mutect2, varscan2
- ATP8A2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as COSV99679800; called by muse, mutect2, varscan2
- ATP8A2 | c.1724G>T p.R575I | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1382573117; called by muse, mutect2, varscan2
- ATP8A2 | c.2168C>T p.S723L | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs1358746880, COSV54970498; called by muse, mutect2, varscan2
- ATP8B1 | c.3716C>T p.A1239V | Missense Mutation (SNP) | VAF 101/723 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs767343941, COSV52177486; called by muse, mutect2, varscan2
- ATP8B1 | c.3010G>A p.D1004N | Missense Mutation (SNP) | VAF 66/627 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1456966019; called by muse, mutect2
- ATP8B1 | c.699-8T>C | Splice Region (SNP) | VAF 53/395 reads (13%) | catalogued as rs752123059; called by muse, mutect2, varscan2
- ATP8B4 | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs759907287; called by muse, mutect2, varscan2
- ATR | c.5153C>T p.A1718V | Missense Mutation (SNP) | VAF 81/497 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63388602; called by muse, mutect2, varscan2
- ATR | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV63384544; called by muse, mutect2, varscan2
- ATR | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 43/377 reads (11%) | catalogued as COSV63394863; called by muse, mutect2, varscan2
- ATRNL1 | c.1002A>G p.L334= | Splice Region (SNP) | VAF 30/182 reads (16%) | catalogued as rs782580582, COSV61818946; called by muse, mutect2
- ATRNL1 | c.3006G>T p.K1002N | Missense Mutation (SNP) | VAF 95/251 reads (38%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.721); catalogued as COSV100372028, COSV58120915; called by muse, mutect2, varscan2
- ATRNL1 | c.4120C>T p.R1374C | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs782456237, COSV100368856, COSV58094648, COSV58105578; called by muse, mutect2, varscan2
- ATXN1L | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 165/592 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs746422084, COSV101449126; called by muse, mutect2, varscan2
- AUH | c.897C>T p.V299= | Splice Region (SNP) | VAF 56/492 reads (11%) | catalogued as COSV57863139; called by muse, mutect2, varscan2
- AUH | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 50/440 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57861830; called by muse, mutect2, varscan2
- AURKA | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 130/496 reads (26%) | catalogued as COSV57170768; called by muse, mutect2, varscan2
- AUTS2 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs756334229; called by muse, mutect2, varscan2
- AVEN | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100145752; called by muse, varscan2
- AVPR1B | c.604T>C p.W202R | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781883502; called by muse, mutect2, varscan2
- AXDND1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 84/526 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs764766519, COSV62642191, COSV62643287; called by muse, mutect2, varscan2
- AXDND1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 24/153 reads (16%) | catalogued as rs148772825; called by muse, mutect2, varscan2
- AXDND1 | c.1230G>T p.K410N | Missense Mutation (SNP) | VAF 36/523 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1283266330, COSV100858556; called by muse, mutect2
- AXIN2 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs878854732; called by muse, mutect2, varscan2
- AXL | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV56576973; called by muse, mutect2, varscan2
- AXL | c.1423C>T p.R475* (on ENST00000301178 / NM_021913.5; = p.R466* on NM_001699.6) | Nonsense Mutation (SNP) | VAF 41/347 reads (12%) | catalogued as rs1307122843; called by muse, mutect2, varscan2
- AXL | c.1447G>T p.E483* (on ENST00000301178 / NM_021913.5; = p.E474* on NM_001699.6) | Nonsense Mutation (SNP) | VAF 37/225 reads (16%) | catalogued as COSV56570784; called by muse, varscan2
- B3GALT6 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.121); catalogued as COSV99767583; called by muse, mutect2, varscan2
- B3GAT3 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 83/631 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs201166537; called by muse, mutect2, varscan2
- B3GLCT | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 82/600 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV58454356; called by muse, varscan2
- B3GNT2 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 73/440 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.536); catalogued as rs1217642451; called by mutect2, varscan2
- B3GNT3 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as rs748234589, COSV100427602; called by muse, mutect2, varscan2
- B3GNT6 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782469643; called by muse, varscan2
- B3GNTL1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1257912253, COSV57950176; called by muse, mutect2, varscan2
- BAALC | c.305G>A p.R102Q (on ENST00000297574 / NM_001364874.1; = p.R67Q on NM_024812.3) | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.478); catalogued as rs200984161; called by muse, mutect2, varscan2
- BACE1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); catalogued as rs528086428, COSV57286125; called by muse, mutect2, varscan2
- BACH1 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104379582; called by mutect2, varscan2
- BAG3 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs556465096, COSV64842531; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- BAG5 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs745996574, COSV54572077; called by muse, varscan2
- BAG5 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 60/441 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as rs1346752934; called by muse, varscan2
- BAHCC1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as COSV57034422; called by muse, varscan2
- BAHD1 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 70/269 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.727); catalogued as rs757855963, COSV69084256; called by muse, mutect2, varscan2
- BAIAP2L1 | c.395C>A p.S132Y | Missense Mutation (SNP) | VAF 52/420 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1472506588; called by muse, varscan2
- BAIAP3 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs142556073; called by muse, mutect2, varscan2
- BAIAP3 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 59/405 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs768496438, COSV60982795; called by muse, mutect2, varscan2
- BAIAP3 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs765382046; called by muse, mutect2, varscan2
- BAMBI | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 49/501 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs369743386; called by muse, mutect2
- BARHL1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55037165, COSV55039029; called by muse, mutect2, varscan2
- BARHL2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 60/744 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as rs1335719892; called by muse, mutect2
- BARHL2 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs1245112855; called by muse, mutect2, varscan2
- BATF | c.109C>A p.R37S | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54375717; called by muse, mutect2, varscan2
- BAZ1B | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 44/452 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59992281; called by muse, varscan2
- BAZ1B | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 31/392 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as rs782307839, COSV59991078, COSV59994858; called by muse, mutect2
- BAZ2B | c.5283G>T p.K1761N | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as rs768935302; called by mutect2, varscan2
- BAZ2B | c.4531G>A p.V1511I | Missense Mutation (SNP) | VAF 66/477 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs184692048; called by muse, mutect2, varscan2
- BAZ2B | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs201182603; called by muse, mutect2
- BBOX1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1379464119, COSV54191958; called by muse, mutect2
- BBS7 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 60/462 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs764507388; called by muse, varscan2
- BCAM | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs139315382; called by mutect2, varscan2
- BCAR3 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs200907769; called by muse, mutect2, varscan2
- BCAS2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 29/201 reads (14%) | catalogued as rs781038404; called by muse, mutect2, varscan2
- BCAT2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV60273709; called by muse, mutect2, varscan2
- BCDIN3D | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 120/482 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs764721935, COSV61702743; called by muse, mutect2, varscan2
- BCKDK | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750916023; called by muse, mutect2, varscan2
- BCL11B | c.1510G>A p.E504K (on ENST00000357195 / NM_001282237.2; = p.E433K on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/364 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.372); catalogued as rs1453421799, COSV100595555; called by muse, mutect2
- BCL2L11 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.105); catalogued as rs1429573443; called by muse, mutect2, varscan2
- BCL2L2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 36/359 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.076); catalogued as rs745978918, COSV51635366; called by muse, varscan2
- BCL6 | c.914G>T p.R305I | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51656666; called by muse, mutect2, varscan2
- BCL9 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV52347137; called by muse, mutect2, varscan2
- BCL9L | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 21/291 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52681952; called by muse, mutect2
- BCLAF1 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 95/333 reads (29%) | catalogued as rs777984166, COSV62143723; called by muse, mutect2, varscan2
- BCOR | c.5041C>T p.R1681C (on ENST00000378444 / NM_001123385.2; = p.R1647C on NM_017745.6) | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs768919602, COSV60702405; called by muse, mutect2, varscan2
- BCOR | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 86/690 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs938251432; called by muse, mutect2, varscan2
- BDKRB1 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 59/465 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs184307206; called by muse, mutect2, varscan2
- BDKRB2 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.091); catalogued as rs144066261; called by muse, mutect2, varscan2
- BDP1 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.44); catalogued as rs375877073, COSV62429856; called by muse, varscan2
- BECN1 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs1312667287; called by muse, mutect2
- BEND2 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as COSV66214937, COSV66217039; called by muse, mutect2
- BEND4 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV101549733; called by muse, mutect2, varscan2
- BEST2 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs951262138; called by muse, mutect2, varscan2
- BEST3 | c.1358C>A p.S453Y | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58299582; called by muse, mutect2
- BFSP1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as COSV64899180; called by muse, mutect2, varscan2
- BFSP2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs200874347, COSV56588428; called by muse, mutect2, varscan2
- BHLHE23 | c.371G>A p.R124Q (on ENST00000370346; = p.R140Q on NM_080606.4) | Missense Mutation (SNP) | VAF 54/530 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100947564; called by muse, mutect2, varscan2
- BICD2 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs749155856; called by muse, mutect2, varscan2
- BICRA | c.2788C>T p.P930S | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as rs755963952; called by muse, mutect2, varscan2
- BIRC2 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 59/402 reads (15%) | catalogued as rs770159483, COSV57161003; called by muse, mutect2, varscan2
- BIRC6 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 52/429 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.921); catalogued as COSV70195793, COSV70201145; called by muse, mutect2, varscan2
- BIRC6 | c.1964A>C p.K655T | Missense Mutation (SNP) | VAF 56/327 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV70196101; called by muse, varscan2
- BIRC6 | c.9817G>A p.E3273K | Missense Mutation (SNP) | VAF 47/580 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70198988; called by muse, mutect2
- BIRC6 | c.10135G>A p.E3379K | Missense Mutation (SNP) | VAF 49/404 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1184411130; called by muse, mutect2, varscan2
- BIRC7 | c.880C>T p.R294C (on ENST00000217169 / NM_139317.3; = p.R276C on NM_022161.4) | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs776089365; called by muse, mutect2, varscan2
- BLM | c.3827C>T p.A1276V | Missense Mutation (SNP) | VAF 150/572 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as rs760554566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BLNK | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 124/598 reads (21%) | catalogued as rs782190491, COSV56411736; called by muse, mutect2, varscan2
- BLOC1S2 | c.371A>C p.K124T | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62489500; called by muse, varscan2
- BLVRB | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs779931948; called by muse, mutect2, varscan2
- BLZF1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs138245508; called by muse, mutect2, varscan2
- BMP2K | c.2965A>C p.M989L | Missense Mutation (SNP) | VAF 92/401 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs376045171; called by muse, mutect2, varscan2
- BMP5 | c.852A>C p.K284N | Missense Mutation (SNP) | VAF 59/535 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.83); catalogued as COSV63704899; called by muse, mutect2, varscan2
- BMP7 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs138140607; called by muse, mutect2, varscan2
- BMP8A | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs757512908; called by muse, mutect2, varscan2
- BMPER | c.918G>T p.K306N | Missense Mutation (SNP) | VAF 53/477 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV51812102; called by muse, mutect2, varscan2
- BMPR2 | c.1757C>A p.S586* | Nonsense Mutation (SNP) | VAF 43/359 reads (12%) | catalogued as COSV65807794; called by muse, mutect2, varscan2
- BMX | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.213); catalogued as rs1305549193; called by muse, mutect2
- BMX | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 69/271 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs1029888196, COSV53023604; called by muse, mutect2, varscan2
- BOD1L1 | c.6221C>T p.S2074F | Missense Mutation (SNP) | VAF 47/425 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50062741; called by muse, mutect2, varscan2
- BOP1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 57/383 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1167544992; called by muse, mutect2, varscan2
- BPHL | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs774197466, COSV66743046; called by muse, mutect2
- BPIFB1 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 43/382 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1349321994, COSV53608720; called by muse, mutect2, varscan2
- BPIFB4 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 65/452 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs372865308; called by muse, mutect2, varscan2
- BRAP | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs934364401; called by muse, mutect2, varscan2
- BRCA1 | c.5035C>A p.L1679I | Missense Mutation (SNP) | VAF 77/562 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as CD108672; called by muse, mutect2, varscan2
- BRCA1 | c.4190G>A p.R1397K | Missense Mutation (SNP) | VAF 59/452 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs767421571, COSV58797796; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA1 | c.2596C>T p.R866C | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs41286300, CM024206, COSV58798327; ClinVar: likely benign / benign / conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.993A>C p.K331N | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); catalogued as rs1060502486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.2234A>C p.K745T | Missense Mutation (SNP) | VAF 46/610 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV66462036; called by muse, mutect2
- BRCA2 | c.2293A>G p.N765D | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as COSV66458172; called by muse, mutect2, varscan2
- BRCA2 | c.7559G>A p.R2520Q | Missense Mutation (SNP) | VAF 70/423 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs80358982, COSV101203989, COSV66452497; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRD1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 140/565 reads (25%) | catalogued as rs777684239; called by muse, mutect2, varscan2
- BRD2 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs137898499; called by muse, mutect2
- BRD4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs867596343, COSV54583236; called by muse, mutect2
- BRD4 | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 100/328 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs769976924; called by muse, mutect2, varscan2
21,577 further variants in this file (14,513 protein-altering or splice-affecting, 4,423 silent, 2,641 other) are not listed here.
